TCGA case TCGA-AR-A0TW — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Mayo. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8da3d6cf-381b-4d1b-93fa-41fd9d2b2e66

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Alive.

Diagnoses (2)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 50.0 years (18,263 days); Year of diagnosis: 2005; Method of diagnosis: Core Biopsy; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Right Upper Outer / Breast, Right Lower Outer.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 27.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Adjuvant; Days to treatment start: 62 days; Days to treatment end: 111 days; Number of cycles: 4; Treatment dose: 4,050 mg; Prescribed dose: 600; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin; Treatment intent type: Adjuvant; Days to treatment start: 62 days; Days to treatment end: 111 days; Number of cycles: 4; Treatment dose: 400 mg; Prescribed dose: 60; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 125 days; Days to treatment end: 167 days; Number of cycles: 4; Treatment dose: 1,200 mg; Prescribed dose: 175; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Age at diagnosis: 52.0 years (19,002 days); Days to diagnosis: 739 days (2.0 years); Prior treatment: Yes.

Follow-up (3 entries)
- Day 739 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 3,009 days (8.2 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 1,966.

Molecular and laboratory tests
- ERBB2 (IHC): Equivocal; Staining intensity value: 2+.
- ERBB2 amplification (FISH): Negative.
- ESR1 (IHC): Positive.
- PGR (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AR-A0TW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 760 mg.
  Slide TCGA-AR-A0TW-01A-01-BSA: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 9; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-AR-A0TW-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 9; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-AR-A0TW-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AR-A0TW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Surgical procedure first: Modified Radical Mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Her2 IHC score: 2+; Method initial path diagnosis: Core needle biopsy; Prospective collection: No; Retrospective collection: Yes.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right Upper Outer Quadrant; Anatomic organ subdivision: Right Lower Outer Quadrant.
- Follow-up form 1: New tumor event diagnosis indicator: Yes.
- Follow-up form 2: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: Cytoxan.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,009 days; disease-specific survival: no event (censored), 3,009 days; disease-free interval: event (new tumor event after initially disease-free), 739 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 739 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AR-A0TW-01A-11D-A087-01): tumor purity 0.48, ploidy 3.27, whole-genome doublings 1.
